Surgical pathology report (de-identified scan), TCGA case TCGA-O1-A52J, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - CALGB, specimen TCGA-O1-A52J-01A (Primary Tumor).

[page 1 of 4]
Patient:

AP Surgical Pathology: Additional Info

Acc: [REDACTED]

Image Cytometry

TISSUE TYPE:

LEFT LOWER LOBE BASILAR SEGMENTECTOMY CONTAINING WELL-DIFFERENTIATED
ADENOCARCINOMA WITH CLARA CELL FEATURES

EPIDERMAL GROWTH FACTOR:

EPIDERMAL GROWTH FACTOR RECEPTOR (EGFR) IMMUNOHISTOCHEMISTRY BY

Approximately 100% of the tumor cells exhibit markedly intense, mostly complete staining of their cell membranes (score 3+), indicating that they strongly express epidermal growth factor receptor. Benign basal bronchiolar epithelial cells stain positively and serve as an internal control.

HER2/neu Immunohistochemistry:

HER2/NEU IMMUNOHISTOCHEMICAL ANALYSIS BY DAKO HERCEPTEST

None of the invasive tumor cells exhibit any staining of their cell membrane (score 0), indicating that they do not overexpress HER2/neu oncoprotein.

INTERPRETATIONS:

TISSUE TYPE: LEFT LOWER LOBE BASILAR SEGMENTECTOMY CONTAINING
WELL-DIFFERENTIATED ADENOCARCINOMA WITH CLARA CELL FEATURES

IMMUNOHISTOCHEMISTRY: STRONGLY POSITIVE (3+) FOR EXPRESSION
OF EPIDERMAL GROWTH FACTOR RECEPTOR.

HER2/NEU IMMUNOHISTOCHEMISTRY: NEGATIVE (0) FOR OVEREXPRESSION OF HER2/NEU
ONCOPROTEIN.

EGFR FISH RESULTS WILL BE ISSUED IN AN ADDENDUM TO THIS REPORT.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

CI ADDENDUM 2:

EGFR FISH

Fluorescence in situ hybridization (FISH) with probes for the EGFR region of chromosome 7 (7p11.1-q11.1) and the centromere of chromosome 7 (D7Z1) was performed on block D5. The EGFR and centromere 7 signals were enumerated in 60 nuclei from an area of the tumor located by comparison with the hematoxylin and eosin and/or immunostained adjacent sections.

RESULTS:

Interphase FISH is nuc ish 7cen(D17Z1x2-10), 7p12(EGFRx2-10) (60). The EGFR to centromere 7 ratio was 1.11 +/- 0.35 (mean +/- 1 S.D.) in a total of 60 tumor cells selected for analysis. An EGFR to D7Z1 ratio greater than 2.00 usually indicates EGFR gene amplification. The percentage of calls with a ratio of 2.00 or greater was 74.

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: lung. @ low lobe c34.3
hw 11/14/12

[page 2 of 4]
The average copy number of EGFR was 5.4.
The percentage of cells with an EGFR copy number of greater than 2.0 was 95%.

The average copy number of centromere 7 was 5.2.
The percentage of cells with a centromere 7 copy number of greater than 2.0 was 95%.

An increased number of chromosome 7 centromeres indicates aneuploidy of chromosome 7 or generalized aneuploidy.

INTERPRETATION:

TISSUE TYPE: LEFT LOWER LOBE BASILAR SEGMENTECTOMY CONTAINING
WELL-DIFFERENTIATED ADENOCARCINOMA WITH CLARA CELL FEATURES
(BLOCK D5).

EGFR FISH INTERPRETATION:

AVERAGE EGFR COPY NUMBER IN 60 TUMOR CELLS WAS 5.4.

95% OF THE TUMOR CELLS HAVE AN INCREASED COPY NUMBER OF THE EGFR GENE

AVERAGE CHROMOSOME 7 COPY NUMBER IN 60 TUMOR CELLS WAS 5.2.

95% OF THE TUMOR CELLS HAVE AN INCREASED COPY NUMBER OF CHROMOSOME 7

RATIO OF EGFR/CHROMOSOME 7 IN 60 TUMOR CELLS WAS 1.11+/-0.35.

7% OF THE TUMOR CELLS HAVE AN INCREASED EGFR/CHROMOSOME 7 RATIO.

METHODOLOGY

EGFR FISH: The epidermal growth factor receptor DNA probe from [redacted] was used to obtain these results. The DNA probe is designed to detect amplification of the EGFR gene via fluorescence in situ hybridization (FISH) in formalin-fixed, paraffin-embedded human cancer tissue specimens.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Electronically signed:

Patient:

Surg Path

CLINICAL HISTORY:
Lung cancer, left lower lobe lesion.

GROSS EXAMINATION:

[page 3 of 4]
83

A. "4R lymph node (AF1)". Received fresh for frozen section is a 0.5 x 0.3 x 0.2 cm aggregate of pink-black tissue frozen entirely as representative AF1 and the frozen section remnant submitted in block A1.

B. "4L lymph node (BF1)". Received fresh for frozen section is a 0.6 x 0.2 x 0.1 cm aggregate of pink-black tissue frozen entirely as representative BF1 and the frozen section remnant submitted in block B1.

C. "Level 7 lymph node (CF1)". Received fresh for frozen section is a 1 x 0.8 x 0.2 cm aggregate of pink-black tissue frozen entirely as representative CF1 and the frozen section remnant submitted in block C1.

D. "Left lower lobe basilar segmentectomy (DF1)". Received fresh for frozen section is a 193 gram (20.1 x 11.2 x 3.2 cm) lobe of lung that has a 2.6 x 2 x 1.2 cm firm gray-tan parenchymal circumscribed mass that is 1.9 cm from the overlying pleura and 0.8 cm from the bronchial and vascular margins which are grossly free of mass. The mass is located approximately in the mid portion of the lobe and a portion of the mass was frozen as representative DF1. The remainder of the parenchyma is spongy red-tan and without additional lesions. The pleura is pink-tan smooth and glistening and intact. Two lobar lymph nodes are identified ranging from 0.3 up to 0.7 cm in greatest dimension.

BLOCK SUMMARY:

- D1- frozen section remnant from DF1
- D2- bronchial and vascular margins en face
- D3-6- representative of mass with D3-4 with overlying pleura
- D7- uninvolved parenchyma away from the mass
- D8- one lobar lymph node
- D9- largest lobar lymph node

E. "Level 10 lymph node". Received unfixed and placed in formalin is a 0.6 x 0.5 x 0.4 cm pink-tan lymph node, bisected and submitted entirely in block E1.

INTRA OPERATIVE CONSULTATION:

- A. "4R lymph node": AF1- negative for malignancy
- B. "4L lymph node": BF1- negative for malignancy
- C. "Level 7 lymph node": CF1- negative for malignancy
- D. "Left lower lobe basilar segmentectomy": DF1 (representative mass)- carcinoma consistent with bronchial alveolar carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE:

PATHOLOGIC STAGE (AJCC 6th Edition): pT1 pN0 pMx

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

- A. "4R LYMPH NODE (AF1)" - NO PATHOLOGIC DIAGNOSIS (NO TUMOR SEEN, 0/1)

[page 4 of 4]
- B. "4L LYMPH NODE (BF1)" - NO PATHOLOGIC DIAGNOSIS (NO TUMOR SEEN, 0/1)
- C. "LEVEL 7 LYMPH NODE (CF1)" - NO PATHOLOGIC DIAGNOSIS (NO TUMOR SEEN, 0/2)
- D. "LEFT LOWER LOBE BASILAR SEGMENTECTOMY (DF1)":

CARCINOMA OF LUNG:

Histologic type: ADENOCARCINOMA WITH CLARA CELL FEATURES
Histologic grade: WELL-DIFFERENTIATED

Extent of invasion
- Max. tumor diameter: 2.6 CM
- Mainstem bronchus: NEGATIVE
- Visceral pleura: NEGATIVE
- Chest wall: N/A
- Mediastinum: N/A
- >1 tumor nodules? NEGATIVE
- Panlobar atelectasis? NEGATIVE

Margins
- Bronchial: NEGATIVE
- Vascular: NEGATIVE
- Parenchymal: NEGATIVE
- Pleural: NEGATIVE

Other prognostic features:
- Vascular invasion: NEGATIVE

Regional lymph nodes: NEGATIVE (0/2)

Additional findings: CENTRILOBULAR EMPHYSEMA, MILD
NON-NECROTIZING GRANULOMA, SMALL, FOCAL

- E. "LEVEL 10 LYMPH NODE" (EXCISION) - NO PATHOLOGIC DIAGNOSIS (NO TUMOR SEEN, 0/1).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

CI ADDENDUM 1:

Please see tests.

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Electronically signed:

Patient:

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file 64d7f340-637e-464f-b0d3-44787ec2cd54 (TCGA-O1-A52J.E5C54019-F404-4F8D-847A-80CF65F65E19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).